Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8R8, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8R8-01A (Primary Tumor).

[page 1 of 4]
ICD-C-3

Thymic carcinoma NOS
808613

Site: Thymus
C379

3/12/14

SURGICAL PATHOLOGY REPORT

* Addendum *

Patient:

MRN:

Accession #:

(Age:) F

Physician:

CC:

Patient Address:

Accession #:

Service:

Date of Procedure:

Date of Receipt:

Date of Report:

....

Clinical Diagnosis & History:

year old female with anterior mediastinal mass. Most likely stage I tumor.

Specimens Submitted:

1: SP: Thymus (fs)

2: SP: Left inferior pole of thymus

DIAGNOSIS:

1. THYMUS; EXCISION:

- THYMIC CARCINOMA WITH FOCAL PLEOMORPHISM (SEE NOTE).
- THE ADJACENT THYMIC PARENCHYMA SHOWS MULTILOCULAR CYSTIC CHANGE.
- NO TUMOR IS SEEN IN THE MARGINS OF RESECTION. HOWEVER, THE TUMOR

EXTENDS TO WITHIN <1MM

OF THE INKED SURFACE.

Pw TSS, 0% pleomorphism on
top slide for T667.

NOTE: IMMUNOHISTOCHEMICAL STAINING SHOWS THE TUMOR IS POSITIVE FOR AE1:AE3, 4A4 (P63), CD5 AND CD117 BUT NEGATIVE FOR CD99. CD3 AND CD5 HIGHLIGHTS THE T-CELLS. THESE FINDINGS SUPPORT THE DIAGNOSIS. EBV (EBER-ISH) WILL BE ORDERED AND THE RESULT WILL BE REPORTED IN AN ADDENDUM.

2. THYMUS, LEFT INFERIOR POLE; EXCISION:

- BENIGN THYMIC TISSUE WITH INVOLUTIONAL CHANGES.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Date of Report:

Page 2 of 3

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for intraoperative consultation, labeled "thymus," and consists of thymus (12 x 8 x 1.5 cm), oriented with a black stitch indicating the right superior pole. The tissue contains a well-circumscribed, white-tan mass (4.0 x 4.0 x 2.5 cm) with a slightly lobulated cut surface, located in the inferior right aspect of the specimen. The mass shows a rounded border with focal infiltration of adipose tissue. The remaining thymic tissue is normal in appearance. The resection margins are inked black. Representative sections submitted.

Summary of sections:

FSC- frozen section control

T- tumor

TH- non-neoplastic thymus

2). The specimen is received in formalin, labeled "Left inferior pole of thymus" and consists of a 1.5 x 1.5 x 0.5 cm oval fragment of lobulated adipose tissue. Entirely inked black, bisected and entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Thymus (fs)

Block	Sect.	Site	PCs
1		fsc	1
10		t	10
2		th	2

Part 2: SP: Left inferior pole of thymus

Block	Sect.	Site	PCs
1		U	2

Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Date of Report:

Page 3 of 3

Date Complete:

By:

Date Reported:

Addendum Diagnosis

IMMUNOHISTOCHEMISTRY SHOWS THE TUMOR IS NEGATIVE FOR EBV (EBER-ISH). THE MORPHOLOGY OF THE TUMOR IS CONSISTENT WITH A THYMIC CARCINOMA WITH LYMPHOEPITHELIOMA-LIKE CARCINOMA FEATURES. THIS CASE WAS SHOWN IN CONSULTATION TO DR. (HEAD AND NECK PATHOLOGY SERVICE) WHO CONCURS WITH THE DIAGNOSIS.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: THYMUS (FS): MALIGNANT EPITHELIAL NEOPLASM, FAVOR CARCINOMA.

PERMANENT DIAGNOSIS: SAME

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: THYMUS (FS): MALIGNANT EPITHELIAL NEOPLASM, FAVOR CARCINOMA.

PERMANENT DIAGNOSIS: SAME

** End of Report **

*Pw TSS, dx discrepancy from
status TCGA tumor to be
Thymic carcinoma, w/ no pleomorphism
BCR*

Diagnosis Discrepancy	pw 119/14	☒
Metastatic Site Discrepancy		☒
Discrepancy in Immunohistochemistry	QUALIFIED	☒

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Thymic Carcinoma with focal pleomorphism	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Thymoma -Thymic Carcinoma (Type C)	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	There is no pleomorphism in the top slide. The tumor original diagnosis indicates focal pleomorphism. This has no bearing in the diagnosis or tumor classification.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	Dr. _____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 17d12a23-22c1-4800-9b90-a23f1c379add (TCGA-XM-A8R8.D9D0551E-1060-4D3E-ADBB-FA0040315595.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).